Gene-level copy-number profile of specimen HCM-SANG-0297-C15-85A from HCMI case HCM-SANG-0297-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0297-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 810b6aa8-5ec5-4e97-a5f6-97adeb2450d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0297-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/e2db3c75-8940-4bda-8407-c0694276891d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 220; copy number 2: 1,642; copy number 3: 15,939; copy number 4: 20,163; copy number 5: 12,887; copy number 6: 4,645; copy number 7: 466; copy number 8: 1,544; copy number 9: 520; copy number 10: 325; copy number 11: 7; copy number 14: 85; copy number 15: 147; copy number 20: 12; copy number 23: 198; copy number 27: 19; copy number 28: 46; copy number 29: 17.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,523,648–49,524,185, 2 genes: AC119751.2, AC119751.8.
- chr22:16,783,412–16,926,444, 13 genes: XKR3, HSFY1P1, GPM6BP3, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,376 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:35,429,064–35,429,277, 1 gene, copy number 9: U3.
- chr5:63,301,523–64,372,869, 4 genes, copy number 9–10: AC025445.1, HTR1A, AC122707.1, RNF180.
- chr5:102,131,007–103,120,138, 13 genes, copy number 10–11: RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68, SLCO6A1, AC094108.1, LINC00492, LINC00491, AC099487.1, AC099487.2, PAM, EIF3KP1, GIN1.
- chr5:180,967,189–181,007,384, 5 genes, copy number 9: AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P.
- chr7:73,567,537–77,783,022, 129 genes, copy number 9–10 (broad region; genes not listed).
- chr7:77,990,384–79,654,227, 18 genes, copy number 9–10: AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234.
- chr7:79,912,104–80,097,215, 2 genes, copy number 9: RNU6-849P, RPL10P11.
- chr7:80,742,538–81,770,438, 10 genes, copy number 9–10: SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF.
- chr7:85,421,122–88,226,993, 26 genes, copy number 9–10 (within-gene range 4–10): LINC00972, AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1.
- chr7:89,882,353–98,629,869, 151 genes, copy number 10–11 (broad region; genes not listed).
- chr11:63,137,867–63,369,718, 1 gene, copy number 10 (within-gene range 3–10): SLC22A10.
- chr11:63,237,957–63,266,256, 3 genes, copy number 10: AP001880.2, CCND2P1, AP001880.1.
- chr11:67,583,742–67,784,229, 17 genes, copy number 29: GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4.
- chr11:68,980,021–109,823,893, 788 genes, copy number 9–28 (broad region; genes not listed).
- chr11:114,343,052–114,454,123, 6 genes, copy number 20 (within-gene range 3–20): AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2.
- chr11:117,427,772–119,381,711, 94 genes, copy number 15–27 (broad region; genes not listed).
- chr11:119,372,706–119,381,613, 1 gene, copy number 15: AP003396.3.
- chr20:30,214,765–30,214,976, 1 gene, copy number 11: CFTRP3.
- chr20:31,377,164–31,412,838, 2 genes, copy number 9: DEFB119, DEFB121.
- chr20:31,739,271–32,809,356, 37 genes, copy number 9: TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B.
- chr20:37,676,889–38,729,372, 38 genes, copy number 9: AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1.
- chr20:45,361,937–45,746,287, 29 genes, copy number 9–10: SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2, WFDC9, WFDC10A, RPS2P7, WFDC11, WFDC10B, WFDC13, MIR3617, SPINT4, HNRNPA1P3.

Autosomal genes at a single copy (total copy number 1): 220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
